Gene-level copy-number profile of tumor specimen MP2PRT-PARLUL-TMP1-A from MP2PRT case MP2PRT-PARLUL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.2 years (1,543 days).
Specimen MP2PRT-PARLUL-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3b4547d9-e349-4a70-aa22-ede052c69adb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PARLUL-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,237 have no estimate.
https://portal.gdc.cancer.gov/files/7d18301c-a19f-4e3f-bb76-b1331fd0c682

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 83; copy number 1: 1,136; copy number 2: 55,721; copy number 3: 1,446.

Homozygous deletions (total copy number 0; autosomes only): 83 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,009,982–89,245,596, 21 genes (within-gene range 0–1): IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30.
- chr2:89,947,512–90,005,629, 6 genes: IGKV2D-29, IGKV2D-28, IGKV1D-27, IGKV2D-26, IGKV3D-25, IGKV2D-24.
- chr2:90,114,838–90,221,384, 9 genes: IGKV3D-15, IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8.
- chr7:38,239,580–38,378,804, 23 genes (within-gene range 0–2): TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6, TRG-AS1, TRGV5P, TRGV5, TRGV4, TRGV3, TRGV2, TRGV1.
- chr14:22,438,547–22,450,139, 4 genes (within-gene range 0–2): TRDD1, TRDD2, TRDD3, TRDJ1.
- chr14:106,276,548–106,301,862, 6 genes (within-gene range 0–1): IGHV1-24, HOMER2P2, LINC00226, IGHV3-25, IGHVIII-25-1, IGHV2-26.
- chr14:106,578,744–106,579,236, 1 gene (within-gene range 0–1): IGHV5-51.
- chr14:106,584,718–106,586,826, 2 genes (within-gene range 0–1): IGHVII-51-2, IGHV3-52.
- chr14:106,680,603–106,771,020, 11 genes: IGHV1-67, SLC20A1P1, IGHVII-67-1, IGHVIII-67-2, IGHVIII-67-3, IGHVIII-67-4, IGHV1-68, IGHV1-69, IGHV2-70D, IGHV1-69D, IGHV2-70.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,136. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
